CCDI case PBCUFJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/4faa9b8a-7b6c-4c91-ac74-96e32a41f521

Demographics
Sex at birth: female.

Biospecimens (3 samples)
- Sample 0DZIWK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DZIX5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DZIXK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
